Surgical pathology report (de-identified scan), TCGA case TCGA-P5-A731, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Cureline, specimen TCGA-P5-A731-01A (Primary Tumor).

ICD-O-3
Oligoastrocytoma, grade II 9382/3
Site: Brain, supratentorial NOS
C71.0

Case #

JS 8/15/13

Patient: Age (years): Gender:

Clinical diagnosis: Brain tumor

Date of procurement:
Sample:

Gross description:

The material presented by grayish soft-elastic pieces of right frontal and temporal lobes.

Microscopic description:

Received material is represented mainly by brain tissue with the adjacent small areas of oligoastrocytoma. WHO Grade II with a large number of calcifications.

Final diagnosis: Oligoastrocytoma: Grade II

II/III/IV Discrepancy		✓

Source: NCI Genomic Data Commons file e590abeb-ea1b-48d3-841c-0161acab0ba1 (TCGA-P5-A731.F22D0DFD-A361-4735-B391-82975EA64AE5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).